Surgical pathology report (de-identified scan), TCGA case TCGA-81-5910, project TCGA-GBM (Glioblastoma Multiforme), tissue source site CHI-Penrose Colorado, specimen TCGA-81-5910-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

SPECIMEN

- A. VOCAL CORD(S) - 1. Right false vocal fold
- B. SOFT TISSUE - 2. Left parietal mass (FS)
- C. SOFT TISSUE - 3. Dura on top of tumor
- D. SOFT TISSUE - 4. Left parietal mass (additional tissue)

CLINICAL INFORMATION

Lesion on voice box; left parietal brain tumor

COPY TO: [REDACTED]

GROSS DESCRIPTION

Received in four parts labeled [REDACTED]

Part A is additionally labeled "right false vocal cord" and consists of two tan-white soft tissue fragments, measuring 2 mm and 5 mm, which are entirely submitted as (A1) with a two-step tag.

Part B is received fresh in the frozen section room and additionally labeled "left parietal mass (frozen section)" and consists of a 15 x 11 x 3 mm aggregate of red-tan soft tissue fragments, which are entirely frozen as FSB1. There is also an additional 18 x 13 x 4 mm aggregate of soft tissue, 2/3 of which is submitted as snap frozen for the [REDACTED]. The remaining tissue from FSB1 is submitted as (B1) and the additional tissue is submitted as (B2).

Frozen section diagnosis by [REDACTED]
Left parietal mass, FSB1 - "Glioblastoma multiforme."

Part C is additionally labeled "dura on top of tumor" and consists of a 3.3 x 2.7 x 0.1 cm portion of glistening white-pink fibrous tissue, which is entirely submitted as (C1) and (C2).

Part D is additionally labeled "left parietal mass (additional tissue)" and consists of a 2.3 x 2.2 x 1.1 cm portion of tan-pink soft tissue. The cut surfaces consists of tan-pink parenchyma with no gross lesions. The specimen is entirely submitted as (D1) and (D2) [REDACTED]

[page 2 of 2]
MICROSCOPIC DESCRIPTION

Step sections of the right false vocal cord specimen show several fragments which include nonkeratinizing squamous epithelium overlying submucosa. The epithelium and submucosa are not inflamed. Focally, the surface orthokeratotic layer shows numerous budding yeast forms consistent with Candida species. Inflammation is not seen. No evidence of squamous dysplasia is found. The features are of Candidiasis without any evidence of tissue invasion by the Candida organisms.

Sections of the left parietal mass show features of a glioblastoma multiforme. This is a cellular neoplasm with some areas show a moderately extensive necrosis. Microvascular proliferation (endothelial proliferation) is prominent multiple areas. The malignant glial cells have pleomorphic, hyperchromatic nuclei with many areas showing indistinct cytoplasmic borders. Some areas include neoplastic gemistocytic astrocytes with eccentrically placed nuclei and a moderate amount eosinophilic cytoplasm. Peri-necrotic pseudopalisades in which neoplastic cells surround necrotic tumor are present. Multinucleate tumor cells are relatively uncommon. No sarcomatous elements are found. The malignant cells are strongly positive with immunohistochemical stain to GFAP. An appropriate control has been verified. Areas to suggest an oligodendroglial component are not identified.

Sections C (dura) showed dense membranous connective tissue. No evidence of a neoplasm is seen. Inflammation is not evident.

Sections D also show a glioblastoma multiforme, similar in appearance to the tumor described in the second specimen.

[REDACTED] has reviewed representative slides of the parietal mass in this case and concurs. [REDACTED]

FINAL DIAGNOSIS

RIGHT FALSE VOCAL CORD

- Candidiasis (noninvasive).
- Benign keratinizing squamous mucosa and submucosa.
- No evidence of dysplasia.

LEFT PARIETAL MASS

- Glioblastoma multiforme.

DURA ON TOP OF TUMOR, EXCISION

- Normal dense membranous connective tissue consistent with dura.

LEFT PARIETAL MASS (ADDITIONAL)

- Glioblastoma multiforme.
- [REDACTED]
- [REDACTED]

Source: NCI Genomic Data Commons file 4f1ac2e1-a072-4e1b-bc41-3caf723ed51c (TCGA-81-5910.9D6E4A44-727E-4713-842E-A75DED996614.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).